Gene-level copy-number profile of tumor specimen TCGA-05-5428-01A from TCGA case TCGA-05-5428, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.7 years (21,061 days).
Specimen TCGA-05-5428-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.a7192d65-4c27-4135-9fea-113525088799.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-5428-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d5ece5ee-29dd-4036-a3f9-3f635ee3d683

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 2,390; copy number 2: 17,631; copy number 3: 19,079; copy number 4: 6,920; copy number 5: 4,596; copy number 6: 6,075; copy number 7: 1,322; copy number 8: 972; copy number 9: 217; copy number 10: 200; copy number 12: 377; copy number 16: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-5428-01A-01D-1624-01): tumor purity 0.63, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:16,299,112–16,766,883, 3 genes (within-gene range 0–5): ATXN1, ATXN1-AS1, AL137003.1.
- chr12:85,955,666–88,142,099, 19 genes (within-gene range 0–2): MGAT4C, AC016993.1, AC139697.1, AC010196.1, AC079597.1, RPL23AP68, AC079598.4, CYCSP30, AC079598.2, MKRN9P, LINC02258, AC079598.1, AC079598.3, RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,100 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:189,989,570–192,011,260, 15 genes, copy number 7: AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1.
- chr2:38,814–51,225,575, 842 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:53,470,447–53,860,160, 6 genes, copy number 7 (within-gene range 3–7): AC069157.2, AC069157.1, ASB3, RNU6-997P, CHAC2, ERLEC1.
- chr2:97,713,576–98,313,299, 6 genes, copy number 8 (within-gene range 2–8): ZAP70, TMEM131, HMGN1P36, RNU7-96P, VWA3B, ATP5F1BP1.
- chr5:58,198–45,895,970, 710 genes, copy number 9–16 (broad region; genes not listed).
- chr7:38,239,580–38,322,730, 13 genes, copy number 8: TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA.
- chr7:120,141,016–159,233,377, 852 genes, copy number 8 (broad region; genes not listed).
- chr8:36,121,398–76,308,315, 645 genes, copy number 7–9 (broad region; genes not listed).
- chr8:135,234,131–137,645,564, 11 genes, copy number 8 (within-gene range 5–8): LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1.

Autosomal genes at a single copy (total copy number 1): 764. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
